FM case AD16500 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5615ecc6-c0d5-4f0d-bc6a-dfc573472c36

Female, 62.7 years: diagnosis not reported by GDC of the breast; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
